Somatic mutation profile of tumor specimen TARGET-10-PASFXA-03A (aliquot TARGET-10-PASFXA-03A-01D) from TARGET case TARGET-10-PASFXA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,374 days).
Specimen TARGET-10-PASFXA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1570162d-73d8-4679-a4e1-bf4d2c24f531.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASFXA-10A (Blood Derived Normal), aliquot TARGET-10-PASFXA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7d43603-d6f1-42b0-b1dc-d82692de234f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 95/99 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAJC7 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 179/468 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV57270273; called by muse, mutect2, varscan2
- OR5M11 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs773176884, COSV73142004; called by muse, mutect2, varscan2
- CDK6 | c.945G>T p.P315= | Silent (SNP) | VAF 100/238 reads (42%) | catalogued as COSV56012983; called by muse, mutect2, varscan2
- CREB1 | c.21C>T p.A7= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as rs1323012635, COSV100783522, COSV62065216, COSV62066741; called by muse, mutect2, varscan2
- GBP6 | c.978C>T p.A326= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as rs755564316, COSV65012567; called by muse, mutect2, varscan2
